Surgical pathology report (de-identified scan), TCGA case TCGA-AG-4001, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-4001-01A (Primary Tumor).

Diagnosis:

Resected colon sample (rectosigmoid) with tumor-free oral and aboral resection margins and including an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue and without local lymph node metastases (G2, pT3 L0 V0 R0 pN0 0/29).

Source: NCI Genomic Data Commons file 3f32d92b-769f-406d-baa3-f762d7c6c1e7 (TCGA-AG-4001.ECEC19F1-2331-4CC4-88B7-F4371A22D8D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).